Somatic mutation profile of tumor specimen C3L-06023-02 (aliquot CPT0361750009) from CPTAC case C3L-06023, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 67.8 years (24,752 days).
Specimen C3L-06023-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8e68b336-ff07-4261-b860-f46b4f255752.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06023-31 (Blood Derived Normal), aliquot CPT0361840002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b11bb3a1-6779-490a-8748-401da1406a69

The open-access MAF lists 610 somatic variants for this specimen: 391 protein-altering or splice-affecting, 193 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 353, Silent 193, Nonsense Mutation 19, Intron 13, Splice Region 6, Frame Shift Del 5, 5'Flank 5, Splice Site 4, 5'UTR 3, RNA 3, 3'UTR 2, Translation Start Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRB1 | c.1913C>T p.S638L | Missense Mutation (SNP) | VAF 249/489 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs267598278, COSV66329373; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 212/459 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- AASS | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 139/545 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV100741766, COSV62789138; called by muse, mutect2, varscan2
- ABCA6 | c.2686C>T p.P896S | Missense Mutation (SNP) | VAF 186/424 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.859); catalogued as COSV52635745; called by muse, mutect2, varscan2
- ADAMTS5 | c.1474G>A p.D492N | Missense Mutation (SNP) | VAF 152/518 reads (29%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.835); catalogued as rs546124249, COSV53175804; called by muse, mutect2, varscan2
- ADAMTS9 | c.1129C>T p.P377S | Missense Mutation (SNP) | VAF 82/294 reads (28%) | SIFT tolerated (0.82); PolyPhen benign (0.092); catalogued as rs1314564514; called by muse, mutect2, varscan2
- ADCY1 | c.837G>A p.M279I | Missense Mutation (SNP) | VAF 113/424 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV52032049; called by muse, mutect2, varscan2
- ADGRV1 | c.4606G>A p.E1536K | Missense Mutation (SNP) | VAF 100/327 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67986931, COSV67992032; called by muse, mutect2, varscan2
- AGAP2 | c.2057G>A p.R686Q (on ENST00000547588 / NM_001122772.2; = p.R350Q on NM_014770.4) | Missense Mutation (SNP) | VAF 58/273 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57729592; called by muse, mutect2, varscan2
- AHNAK2 | c.11506G>A p.D3836N | Missense Mutation (SNP) | VAF 94/605 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as rs969445196; called by muse, mutect2, varscan2
- ALK | c.2678G>A p.G893E | Missense Mutation (SNP) | VAF 128/393 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66559739; called by muse, mutect2, varscan2
- ANGPT1 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 78/286 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52433501; called by muse, mutect2, varscan2
- ANKEF1 | c.2218G>A p.E740K | Missense Mutation (SNP) | VAF 81/323 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV65693748; called by muse, mutect2, varscan2
- ANKRD35 | c.931C>T p.R311W | Missense Mutation (SNP) | VAF 234/532 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.54); catalogued as rs587625379; called by muse, mutect2, varscan2
- ARAF | c.909G>A p.W303* | Nonsense Mutation (SNP) | VAF 49/471 reads (10%) | catalogued as COSV51693112; called by muse, mutect2, varscan2
- ARHGEF2 | c.1691G>A p.R564Q (on ENST00000361247 / NM_001162383.2; = p.R536Q on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/571 reads (11%) | SIFT tolerated (1); PolyPhen possibly damaging (0.788); catalogued as COSV100561275; called by muse, mutect2, varscan2
- BRINP1 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 33/474 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as rs751806082, COSV56302273; called by muse, mutect2
- BRPF1 | c.3346C>T p.H1116Y | Missense Mutation (SNP) | VAF 88/382 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.286); catalogued as COSV57353075; called by muse, mutect2, varscan2
- BSN | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 156/594 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56521225; called by muse, mutect2, varscan2
- BTBD11 | c.1462C>T p.P488S | Missense Mutation (SNP) | VAF 91/279 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.696); catalogued as COSV55039666; called by muse, mutect2, varscan2
- BTN3A3 | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 150/565 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.251); catalogued as rs138755245; called by muse, mutect2, varscan2
- C14orf39 | c.1612C>T p.P538S | Missense Mutation (SNP) | VAF 86/291 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs750004099; called by muse, mutect2, varscan2
- C2CD4D | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 302/666 reads (45%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.881); catalogued as COSV63256158; called by muse, mutect2, varscan2
- C8orf34 | c.691C>T p.Q231* | Nonsense Mutation (SNP) | VAF 117/362 reads (32%) | catalogued as rs866337168; called by muse, mutect2, varscan2
- CAPN13 | c.557G>A p.G186D | Missense Mutation (SNP) | VAF 110/370 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1171686520; called by muse, mutect2, varscan2
- CATSPERB | c.2905C>T p.P969S | Missense Mutation (SNP) | VAF 115/359 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV56422541; called by muse, mutect2, varscan2
- CCDC152 | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 85/228 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs865979371, COSV100736676; called by muse, mutect2, varscan2
- CCDC175 | c.1472G>A p.R491Q | Missense Mutation (SNP) | VAF 61/201 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.689); catalogued as rs907096885, COSV55788130; called by muse, mutect2, varscan2
- CD19 | c.1606G>A p.D536N (on ENST00000324662 / NM_001178098.2; = p.D535N on NM_001770.6) | Missense Mutation (SNP) | VAF 171/677 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.412); catalogued as rs1246353532; called by muse, mutect2, varscan2
- CD200R1L | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 117/454 reads (26%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as COSV68004140; called by muse, mutect2, varscan2
- CD8B2 | c.241C>T p.H81Y | Missense Mutation (SNP) | VAF 132/451 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs866650064; called by muse, mutect2, varscan2
- CD96 | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 82/213 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99343443; called by muse, mutect2, varscan2
- CDH12 | c.613G>A p.G205R | Missense Mutation (SNP) | VAF 52/217 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1161269651, COSV66446852; called by muse, mutect2, varscan2
- CDH15 | c.1904G>C p.R635P | Missense Mutation (SNP) | VAF 108/465 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.94); catalogued as rs753262958, COSV99228543; called by muse, mutect2, varscan2
- CELSR3 | c.7585C>T p.R2529C | Missense Mutation (SNP) | VAF 91/302 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747265256; called by muse, mutect2, varscan2
- CFAP46 | c.5668G>A p.E1890K | Missense Mutation (SNP) | VAF 58/511 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV54154369; called by muse, mutect2, varscan2
- CHIA | c.658G>A p.G220S (on ENST00000343320; = p.G112S on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 171/453 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0.129); catalogued as COSV58475855; called by muse, mutect2, varscan2
- CNGA3 | c.800G>A p.G267D | Missense Mutation (SNP) | VAF 88/338 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs781673067, CM014537; called by muse, mutect2, varscan2
- CNTNAP2 | c.683G>T p.G228V | Missense Mutation (SNP) | VAF 88/415 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as COSV62202038; called by muse, mutect2, varscan2
- COL6A5 | c.7495C>T p.P2499S (on ENST00000312481; = p.P2495S on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/308 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55217573; called by muse, mutect2, varscan2
- COQ6 | c.1095-1G>A p.X365_splice | Splice Site (SNP) | VAF 75/303 reads (25%) | catalogued as rs1301428264, COSV99474122; called by muse, mutect2, varscan2
- COQ6 | c.1095G>A p.G365= | Splice Region (SNP) | VAF 76/303 reads (25%) | catalogued as COSV53178927; called by muse, mutect2, varscan2
- CPSF6 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 134/429 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV99879276; called by muse, mutect2, varscan2
- CSMD1 | c.6346C>T p.P2116S (on ENST00000520002; = p.P2115S on NM_033225.6) | Missense Mutation (SNP) | VAF 104/295 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs865819789, COSV59343338; called by muse, mutect2, varscan2
- CSMD2 | c.2273C>T p.S758L | Missense Mutation (SNP) | VAF 68/318 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as rs901155048, COSV53897001; called by muse, mutect2, varscan2
- CTNNA2 | c.2714C>T p.S905F (on ENST00000402739 / NM_001282597.3; = p.S857F on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 118/388 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.796); catalogued as COSV58161923; called by muse, mutect2, varscan2
- CYYR1 | c.88C>T p.Q30* | Nonsense Mutation (SNP) | VAF 84/318 reads (26%) | catalogued as rs200563289; called by muse, mutect2, varscan2
- DAAM1 | c.1708C>T p.P570S | Missense Mutation (SNP) | VAF 162/500 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs866795002; called by muse, mutect2, varscan2
- DCLRE1A | c.1700C>T p.P567L | Missense Mutation (SNP) | VAF 106/290 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs1251928128; called by muse, mutect2, varscan2
- DCTN2 | c.622G>A p.E208K (on ENST00000548249 / NM_001261413.2; = p.E213K on NM_006400.4) | Missense Mutation (SNP) | VAF 125/409 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV63075385; called by muse, mutect2, varscan2
- DEFB118 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 76/282 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs865858698, COSV53620402; called by muse, mutect2, varscan2
- DIRAS2 | c.19G>A p.D7N | Missense Mutation (SNP) | VAF 79/300 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65370224; called by muse, mutect2, varscan2
- DLG2 | c.134C>T p.S45L | Missense Mutation (SNP) | VAF 113/316 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.843); catalogued as COSV101070251, COSV65878993; called by muse, mutect2, varscan2
- DMP1 | c.34G>A p.G12R | Missense Mutation (SNP) | VAF 95/318 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV56820915; called by muse, mutect2, varscan2
- DNAH1 | c.6629C>T p.S2210F | Missense Mutation (SNP) | VAF 101/367 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as rs747404874; called by muse, mutect2, varscan2
- DNAH17 | c.11599G>A p.E3867K | Missense Mutation (SNP) | VAF 196/471 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs370262501; called by muse, mutect2, varscan2
- DNAH3 | c.10695G>A p.M3565I | Missense Mutation (SNP) | VAF 80/392 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as rs1567528819; called by muse, mutect2, varscan2
- DNAH5 | c.10772G>A p.G3591E | Missense Mutation (SNP) | VAF 117/446 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54214966, COSV99451847; called by muse, mutect2, varscan2
- DNAH5 | c.9130G>A p.E3044K | Missense Mutation (SNP) | VAF 82/310 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54236590; called by muse, mutect2, varscan2
- DOC2B | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 29/532 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1555522465; called by muse, mutect2
- DPT | c.514A>G p.T172A | Missense Mutation (SNP) | VAF 54/413 reads (13%) | SIFT tolerated (0.76); PolyPhen benign (0.08); catalogued as rs1234279960; called by muse, mutect2, varscan2
- ESYT3 | c.997C>T p.P333S | Missense Mutation (SNP) | VAF 109/404 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100004771; called by muse, mutect2, varscan2
- F13B | c.884G>A p.G295E | Missense Mutation (SNP) | VAF 96/474 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745474835, COSV66374436; called by muse, mutect2, varscan2
- FBLN2 | c.536G>A p.G179E | Missense Mutation (SNP) | VAF 151/572 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.118); catalogued as rs751166659; called by muse, mutect2, varscan2
- FER1L5 | c.1656G>A p.G552= (on ENST00000623019; = p.G557= on NM_001293083.2) | Splice Region (SNP) | VAF 53/192 reads (28%) | catalogued as COSV70069553; called by muse, mutect2, varscan2
- FGL2 | c.613+1G>A p.X205_splice | Splice Site (SNP) | VAF 186/480 reads (39%) | catalogued as rs909809705; called by muse, mutect2, varscan2
- FMN2 | c.1741C>T p.P581S | Missense Mutation (SNP) | VAF 91/572 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.573); catalogued as COSV100146155; called by muse, mutect2, varscan2
- FRAS1 | c.1112G>A p.G371E | Missense Mutation (SNP) | VAF 70/247 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); catalogued as COSV53645466; called by muse, mutect2, varscan2
- GAPDHS | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 200/508 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV55882997; called by muse, mutect2, varscan2
- GK2 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 114/370 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62626694; called by muse, mutect2, varscan2
- GLI2 | c.1630G>A p.E544K (on ENST00000361492 / NM_001374353.1; = p.E561K on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/336 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs772471844, COSV58036758; called by muse, mutect2, varscan2
- GLRB | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 65/199 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV100029645, COSV52417998; called by muse, mutect2, varscan2
- GOLGA5 | c.2020C>T p.R674C | Missense Mutation (SNP) | VAF 97/351 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774532511, COSV50832463; called by muse, mutect2, varscan2
- HNRNPCL1 | c.145C>T p.H49Y | Missense Mutation (SNP) | VAF 72/319 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV100509030; called by muse, mutect2, varscan2
- HS6ST3 | c.242G>A p.G81E | Missense Mutation (SNP) | VAF 74/295 reads (25%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs1223921065, COSV65015193; called by muse, mutect2, varscan2
- HYDIN | c.13329G>A p.M4443I | Missense Mutation (SNP) | VAF 30/246 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs1210711584; called by muse, mutect2, varscan2
- IGHG2 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 169/543 reads (31%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.717); catalogued as rs753096665; called by muse, mutect2, varscan2
- IL1RAPL1 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 153/496 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs199864130, COSV56250433; called by muse, mutect2, varscan2
- IL3RA | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 89/349 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.301); catalogued as rs753510585, COSV58430644; called by muse, mutect2, varscan2
- KCNB2 | c.2434G>A p.D812N | Missense Mutation (SNP) | VAF 154/450 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.298); catalogued as rs757936160; called by muse, mutect2, varscan2
- KDM6B | c.1163C>T p.S388F | Missense Mutation (SNP) | VAF 164/479 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as rs377179034; called by muse, mutect2, varscan2
- KIAA1109 | c.649C>T p.H217Y | Missense Mutation (SNP) | VAF 77/266 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.777); catalogued as COSV52678553; called by muse, mutect2, varscan2
- KIF21A | c.2830G>A p.E944K (on ENST00000361418 / NM_001378440.1; = p.E931K on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/312 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM071824; called by muse, mutect2, varscan2
- KIF6 | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 92/351 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54696334; called by muse, mutect2, varscan2
- KL | c.2146G>A p.E716K | Missense Mutation (SNP) | VAF 112/376 reads (30%) | SIFT tolerated (0.74); PolyPhen benign (0.006); catalogued as rs867359183, COSV66307933; called by muse, mutect2, varscan2
- KRT1 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 84/311 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1280274048, COSV52869236; called by muse, mutect2, varscan2
- KRTAP9-3 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 64/541 reads (12%) | SIFT deleterious (0); catalogued as rs1270246041; called by muse, mutect2, varscan2
- LAMA5 | c.2227C>T p.P743S | Missense Mutation (SNP) | VAF 77/292 reads (26%) | SIFT tolerated (0.85); PolyPhen benign (0.005); catalogued as COSV99438806; called by muse, mutect2, varscan2
- LASP1 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 31/250 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as COSV100530297; called by muse, mutect2, varscan2
- LCTL | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 100/385 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV58422008; called by muse, mutect2, varscan2
- LYST | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 251/517 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1473462652; called by muse, mutect2, varscan2
- MAB21L3 | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 125/599 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.231); catalogued as COSV65674234; called by muse, mutect2, varscan2
- MAGEB1 | c.663G>A p.W221* | Nonsense Mutation (SNP) | VAF 148/572 reads (26%) | catalogued as rs777909623, COSV66775681; called by muse, mutect2, varscan2
- MAGEB18 | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 150/532 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs773051777; called by muse, mutect2, varscan2
- MAPKAPK5 | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 55/341 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV72431669; called by muse, mutect2, varscan2
- MARCHF1 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 61/211 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV56815496; called by muse, mutect2, varscan2
- MEN1 | c.19C>T p.Q7* | Nonsense Mutation (SNP) | VAF 56/171 reads (33%) | catalogued as CM1313626; called by muse, mutect2, varscan2
- MFF | c.1021C>T p.R341C | Missense Mutation (SNP) | VAF 50/234 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as rs374804976, COSV58826434; called by muse, mutect2, varscan2
- MMP21 | c.1433G>A p.R478K | Missense Mutation (SNP) | VAF 20/264 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.065); catalogued as COSV61763064; called by muse, mutect2
- MUC12 | c.15476C>T p.S5159F (on ENST00000379442; = p.S5016F on NM_001164462.1) | Missense Mutation (SNP) | VAF 130/340 reads (38%) | SIFT tolerated (0.17); catalogued as rs1018499714; called by muse, mutect2, varscan2
- MUC6 | c.4238G>A p.G1413E | Missense Mutation (SNP) | VAF 178/446 reads (40%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.012); catalogued as rs1554897504, COSV70144436; called by muse, varscan2
- MYO18B | c.1102G>A p.D368N | Missense Mutation (SNP) | VAF 139/468 reads (30%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.068); catalogued as rs769977839, COSV59148718; called by muse, mutect2, varscan2
- MYO18B | c.5347G>A p.G1783R | Missense Mutation (SNP) | VAF 103/311 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs763419722, COSV100122933; called by muse, mutect2, varscan2
- NCKAP1L | c.2275G>A p.G759S | Missense Mutation (SNP) | VAF 129/482 reads (27%) | SIFT tolerated (0.82); PolyPhen benign (0.007); catalogued as rs1258955938; called by muse, mutect2, varscan2
- NEURL4 | c.2270G>C p.R757P | Missense Mutation (SNP) | VAF 90/291 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59748604; called by muse, mutect2, varscan2
- NFATC4 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 136/480 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV51600215; called by muse, varscan2
- NHS | c.2758G>A p.E920K | Missense Mutation (SNP) | VAF 134/537 reads (25%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as rs771048907, COSV66273272; called by muse, mutect2, varscan2
- NOTCH2 | c.6593C>T p.A2198V | Missense Mutation (SNP) | VAF 138/658 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.039); catalogued as COSV56680403; called by muse, mutect2, varscan2
- NPAS1 | c.1324C>T p.P442S | Missense Mutation (SNP) | VAF 54/391 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.055); catalogued as rs1255183902, COSV53409181; called by muse, mutect2, varscan2
- OBSCN | c.11872G>A p.E3958K | Missense Mutation (SNP) | VAF 117/592 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs746344428, COSV52751636; called by muse, mutect2, varscan2
- OR10W1 | c.864G>A p.M288I | Missense Mutation (SNP) | VAF 99/244 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV67720858; called by muse, mutect2, varscan2
- OR11H1 | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 109/1105 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as COSV99421539; called by muse, mutect2
- OR14I1 | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 356/705 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV61199000, COSV61199650; called by muse, mutect2, varscan2
- OR2L8 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 230/477 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100594144, COSV61726435; called by muse, mutect2, varscan2
- OR4D11 | c.455G>A p.G152D | Missense Mutation (SNP) | VAF 119/304 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs772782356, COSV57585758, COSV57585989; called by muse, mutect2, varscan2
- OR4F6 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 119/399 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.764); catalogued as COSV61026880; called by muse, mutect2, varscan2
- OR4K15 | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 80/316 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as rs755018034, COSV59301089; called by muse, mutect2, varscan2
- OR4N2 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 117/583 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs866280852, COSV60050102; called by muse, mutect2, varscan2
- OR51Q1 | c.434G>A p.R145K | Missense Mutation (SNP) | VAF 71/356 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs921982383; called by muse, mutect2, varscan2
- P3H2 | c.1565G>A p.R522Q | Missense Mutation (SNP) | VAF 66/280 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs139465966; called by muse, mutect2, varscan2
- PAK5 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 100/435 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.949); catalogued as rs764351685, COSV62020360; called by muse, mutect2, varscan2
- PAK5 | c.386C>T p.S129F | Missense Mutation (SNP) | VAF 110/415 reads (27%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.888); catalogued as rs1262495622, COSV62022080; called by muse, mutect2, varscan2
- PAPPA | c.3188C>T p.S1063F | Missense Mutation (SNP) | VAF 90/338 reads (27%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.962); catalogued as COSV60278038, COSV60279223, COSV60287666; called by muse, mutect2, varscan2
- PASD1 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 62/268 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV64855120; called by muse, mutect2, varscan2
- PAX8 | c.865C>T p.L289F | Missense Mutation (SNP) | VAF 117/439 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as rs1373772352; called by muse, mutect2, varscan2
- PCDH1 | c.2524C>T p.P842S | Missense Mutation (SNP) | VAF 63/463 reads (14%) | SIFT tolerated (0.2); PolyPhen probably damaging (1); catalogued as COSV54614449; called by muse, mutect2, varscan2
- PCDHGA1 | c.905C>T p.S302L | Missense Mutation (SNP) | VAF 55/363 reads (15%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.029); catalogued as rs1285679219, COSV100966123, COSV65297246; called by muse, mutect2, varscan2
- PCLO | c.12611C>T p.S4204L | Missense Mutation (SNP) | VAF 90/393 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61617546; called by muse, mutect2, varscan2
- PCLO | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 152/433 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as rs372528729; called by muse, mutect2, varscan2
- PEG3 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 37/356 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV104380787; called by muse, mutect2
- PHACTR2 | c.94G>A p.G32R | Missense Mutation (SNP) | VAF 136/473 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99992122; called by muse, mutect2, varscan2
- PIGG | c.1490C>T p.S497L (on ENST00000453061 / NM_001127178.3; = p.S489L on NM_017733.4) | Missense Mutation (SNP) | VAF 152/529 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs755547556, COSV56316311; called by muse, mutect2, varscan2
- PIWIL4 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 74/190 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.342); catalogued as rs758783384, COSV54410160; called by muse, mutect2
- PKD1 | c.9674C>T p.A3225V | Missense Mutation (SNP) | VAF 80/390 reads (21%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.785); catalogued as rs1198499786; called by muse, mutect2, varscan2
- PKHD1L1 | c.2287C>T p.Q763* | Nonsense Mutation (SNP) | VAF 52/220 reads (24%) | catalogued as COSV65745070; called by muse, mutect2, varscan2
- PLEKHF2 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 80/332 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.893); catalogued as rs750958489, COSV59541757; called by muse, mutect2, varscan2
- PLXDC2 | c.1171C>T p.R391* | Nonsense Mutation (SNP) | VAF 86/206 reads (42%) | catalogued as rs1335007275, COSV65905846; called by muse, mutect2, varscan2
- POC1A | c.1003C>T p.P335S | Missense Mutation (SNP) | VAF 43/365 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs1479211661; called by muse, mutect2, varscan2
- PPBP | c.217C>T p.H73Y | Missense Mutation (SNP) | VAF 116/461 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs745503298, COSV56020004; called by muse, mutect2, varscan2
- PPIL2 | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 81/311 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs774111395; called by muse, mutect2, varscan2
- PPP1R2B | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 104/332 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.05); catalogued as rs546353522, COSV70372745; called by muse, mutect2, varscan2
- PTPRE | c.1721A>G p.N574S | Missense Mutation (SNP) | VAF 72/205 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs780978073; called by muse, mutect2, varscan2
- PTPRN2 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 156/487 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1475283861, COSV101234904, COSV67059274; called by muse, mutect2, varscan2
- PTPRR | c.1258C>T p.R420C | Missense Mutation (SNP) | VAF 66/247 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1174021927, COSV51726925; called by muse, mutect2, varscan2
- RAF1 | c.596C>T p.S199F | Missense Mutation (SNP) | VAF 67/257 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV52582799; called by muse, mutect2, varscan2
- RAG1 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 124/309 reads (40%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.014); catalogued as rs1343229886, COSV55028242; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RBBP6 | c.4693C>T p.P1565S | Missense Mutation (SNP) | VAF 130/412 reads (32%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as COSV60507291; called by muse, mutect2, varscan2
- RETREG2 | c.644T>C p.L215S | Missense Mutation (SNP) | VAF 55/218 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs781412642; called by muse, mutect2, varscan2
- RFX6 | c.1852C>T p.P618S | Missense Mutation (SNP) | VAF 125/372 reads (34%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.001); catalogued as COSV60586024; called by muse, mutect2, varscan2
- RGPD3 | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 76/307 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV58739693; called by muse, mutect2, varscan2
- RGPD4 | c.2972C>T p.P991L | Missense Mutation (SNP) | VAF 64/429 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.771); catalogued as rs2919159, COSV100736248; called by muse, mutect2, varscan2
- RTL4 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 137/494 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.136); catalogued as rs1391421694, COSV61206657; called by muse, mutect2, varscan2
- S100A7L2 | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 172/367 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs747618607; called by muse, mutect2, varscan2
- S1PR1 | c.1044G>A p.M348I | Missense Mutation (SNP) | VAF 131/432 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100541509; called by muse, mutect2, varscan2
- SDK2 | c.380G>A p.G127E | Missense Mutation (SNP) | VAF 129/650 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1334842718; called by muse, mutect2, varscan2
- SEC16A | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 92/602 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV51534634; called by muse, mutect2, varscan2
- SEMA4D | c.2564C>T p.A855V | Missense Mutation (SNP) | VAF 38/364 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1349528599; called by muse, mutect2, varscan2
- SERPINI2 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 54/220 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.012); catalogued as COSV52988378; called by muse, mutect2, varscan2
- SGCZ | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 73/184 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267601802, COSV65998392, COSV66047381; called by muse, mutect2, varscan2
- SH3RF2 | c.512G>A p.S171N | Missense Mutation (SNP) | VAF 129/408 reads (32%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.795); catalogued as rs780317344, COSV63041684; called by muse, mutect2, varscan2
- SH3TC2 | c.1052C>T p.A351V | Missense Mutation (SNP) | VAF 106/316 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100102001, COSV60462311; called by muse, mutect2, varscan2
- SLC50A1 | c.548G>C p.R183T | Missense Mutation (SNP) | VAF 198/440 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.044); catalogued as COSV57596612; called by muse, mutect2, varscan2
- SLC6A4 | c.1870G>A p.D624N | Missense Mutation (SNP) | VAF 29/253 reads (11%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.534); catalogued as COSV55567813; called by muse, mutect2, varscan2
- SLFN5 | c.1841C>T p.P614L | Missense Mutation (SNP) | VAF 35/248 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.071); catalogued as rs1489169016; called by muse, mutect2, varscan2
- SPDYE16 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 42/182 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as rs1425620563; called by muse, mutect2, varscan2
- SSH1 | c.2657C>T p.A886V | Missense Mutation (SNP) | VAF 70/404 reads (17%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs780341554; called by muse, mutect2, varscan2
- ST3GAL1 | c.242C>T p.T81I | Missense Mutation (SNP) | VAF 142/508 reads (28%) | PolyPhen benign (0.033); catalogued as rs199767300, COSV100172145, COSV60611175; called by muse, mutect2, varscan2
- STRN | c.1945C>T p.R649C | Missense Mutation (SNP) | VAF 51/344 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.608); catalogued as rs772420673; called by muse, mutect2, varscan2
- SV2A | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 118/586 reads (20%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.001); catalogued as rs1553764161; called by muse, mutect2, varscan2
- SYT8 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 128/392 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs745846045, COSV53288564; called by mutect2, varscan2
- TAF1L | c.1838C>T p.P613L | Missense Mutation (SNP) | VAF 178/419 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1301655205; called by muse, mutect2, varscan2
- THBS4 | c.364G>A p.G122R | Missense Mutation (SNP) | VAF 107/382 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs774397823; called by muse, mutect2, varscan2
- THEMIS | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 77/263 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100965418; called by muse, mutect2, varscan2
- TKTL2 | c.299A>G p.N100S | Missense Mutation (SNP) | VAF 121/427 reads (28%) | SIFT tolerated (0.69); PolyPhen benign (0.011); catalogued as COSV99761405; called by muse, mutect2, varscan2
- TLR4 | c.1150G>A p.G384S (on ENST00000355622 / NM_138554.5; = p.G344S on NM_003266.4) | Missense Mutation (SNP) | VAF 104/361 reads (29%) | SIFT tolerated (0.82); PolyPhen benign (0.006); catalogued as rs868822246, COSV62923767; called by muse, mutect2, varscan2
- TLR9 | c.1588C>T p.H530Y | Missense Mutation (SNP) | VAF 92/441 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as rs756928475; called by muse, mutect2, varscan2
- TMEM43 | c.757C>T p.P253S | Missense Mutation (SNP) | VAF 136/490 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60146380; called by muse, mutect2, varscan2
- TNRC18 | c.4531G>A p.E1511K | Missense Mutation (SNP) | VAF 86/382 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.335); catalogued as rs1353041990; called by muse, mutect2, varscan2
- TOPBP1 | c.346del p.L116Wfs*15 | Frame Shift Del (DEL) | VAF 48/166 reads (29%) | catalogued as COSV53435076; called by mutect2, varscan2
- TOPBP1 | c.345T>A p.S115R | Missense Mutation (SNP) | VAF 50/174 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1559835279; called by mutect2, varscan2
- TPH2 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 89/361 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.901); catalogued as COSV100422458; called by muse, mutect2, varscan2
- TPTE | c.1456C>T p.P486S (on ENST00000618007 / NM_199261.4; = p.P468S on NM_199259.4) | Missense Mutation (SNP) | VAF 31/228 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); catalogued as rs757759527; called by muse, mutect2, varscan2
- TRANK1 | c.5879C>T p.S1960F | Missense Mutation (SNP) | VAF 127/500 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV100081189; called by muse, mutect2, varscan2
- TRAV10 | c.106G>T p.E36* | Nonsense Mutation (SNP) | VAF 109/360 reads (30%) | catalogued as rs751972722; called by muse, mutect2, varscan2
- TRHDE | c.2164G>A p.D722N | Missense Mutation (SNP) | VAF 110/384 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.563); catalogued as rs1306640866, COSV53835012; called by muse, mutect2, varscan2
- TRIM7 | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 67/573 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as rs764659374, COSV51241537; called by muse, mutect2, varscan2
- TRPV5 | c.1518C>T p.S506= | Splice Region (SNP) | VAF 121/461 reads (26%) | catalogued as rs140469115; called by muse, mutect2, varscan2
- TTN | c.45280G>A p.D15094N (on ENST00000591111; = p.D7670N on NM_003319.4) | Missense Mutation (SNP) | VAF 84/300 reads (28%) | PolyPhen possibly damaging (0.69); catalogued as rs773927256, COSV60167472; called by muse, mutect2, varscan2
- TTN | c.23114G>A p.G7705E (on ENST00000591111; = p.G6778E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 152/500 reads (30%) | PolyPhen probably damaging (1); catalogued as COSV60360516; called by muse, mutect2, varscan2
- TTN | c.18632G>A p.R6211K (on ENST00000591111; = p.R5284K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 127/448 reads (28%) | PolyPhen benign (0.001); catalogued as rs779960008, COSV60250664; called by muse, mutect2, varscan2
- TUT4 | c.3016C>A p.R1006S | Missense Mutation (SNP) | VAF 89/378 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV57118968; called by muse, mutect2, varscan2
- UBC | c.2056T>C p.*686Qext*17 | Nonstop Mutation (SNP) | VAF 82/268 reads (31%) | catalogued as rs767955417; called by muse, mutect2, varscan2
- USH2A | c.1272G>A p.M424I | Missense Mutation (SNP) | VAF 117/525 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV100232384; called by muse, mutect2, varscan2
- VPS13C | c.4775C>T p.S1592F (on ENST00000644861 / NM_020821.3; = p.S1549F on NM_017684.5) | Missense Mutation (SNP) | VAF 69/224 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as rs11629838; called by muse, mutect2, varscan2
- VSIG4 | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 117/477 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as rs748025880; called by muse, mutect2, varscan2
- WDR19 | c.1534C>T p.R512* | Nonsense Mutation (SNP) | VAF 67/264 reads (25%) | catalogued as rs1476588496, COSV56463923; called by muse, mutect2, varscan2
- WDR81 | c.2054C>T p.A685V | Missense Mutation (SNP) | VAF 167/423 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs770370520; called by muse, mutect2, varscan2
- ZCCHC12 | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 106/434 reads (24%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); catalogued as rs1212891619, COSV59571293; called by muse, mutect2, varscan2
- ZCCHC14 | c.1160C>T p.P387L (on ENST00000268616; = p.P524L on NM_015144.3) | Missense Mutation (SNP) | VAF 137/529 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs780814188, COSV51886447; called by muse, mutect2, varscan2
- ZFHX4 | c.9778G>A p.G3260R | Missense Mutation (SNP) | VAF 114/474 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs371057088, COSV99265743; called by muse, mutect2, varscan2
- ZFHX4 | c.9779G>A p.G3260E | Missense Mutation (SNP) | VAF 116/480 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV50690485; called by muse, mutect2, varscan2
- ZNF432 | c.1278G>T p.E426D | Missense Mutation (SNP) | VAF 42/571 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs765063035, COSV55415333; called by muse, mutect2
- ZNF536 | c.3664G>A p.V1222I | Missense Mutation (SNP) | VAF 238/545 reads (44%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs779887993, COSV62836041; called by muse, mutect2, varscan2
- ZNF556 | c.1346G>A p.G449E | Missense Mutation (SNP) | VAF 146/261 reads (56%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as COSV56911380; called by muse, mutect2, varscan2
- ZNF804A | c.2662C>T p.P888S | Missense Mutation (SNP) | VAF 117/449 reads (26%) | SIFT tolerated (0.77); PolyPhen benign (0.03); catalogued as COSV56467694; called by muse, mutect2, varscan2
- ZNF804A | c.2903C>T p.S968F | Missense Mutation (SNP) | VAF 100/355 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV56464028, COSV56475340; called by muse, mutect2, varscan2
- ADAMTSL2 | c.2075C>T p.S692L | Missense Mutation (SNP) | VAF 132/498 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- AHI1 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 126/429 reads (29%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- AKAP11 | c.5458T>C p.C1820R | Missense Mutation (SNP) | VAF 55/376 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ALDOB | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 117/338 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ALG3 | c.638T>C p.L213P | Missense Mutation (SNP) | VAF 116/395 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- AMER3 | c.308G>A p.R103K | Missense Mutation (SNP) | VAF 160/599 reads (27%) | SIFT tolerated (0.98); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ANK3 | c.7739C>T p.T2580I | Missense Mutation (SNP) | VAF 109/306 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANKRD50 | c.2921C>G p.A974G | Missense Mutation (SNP) | VAF 54/469 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- ARMC4 | c.2591C>T p.P864L | Missense Mutation (SNP) | VAF 85/218 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- ATAD2 | c.2317G>A p.D773N | Missense Mutation (SNP) | VAF 50/186 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- B3GALT4 | c.1117del p.I373* | Frame Shift Del (DEL) | VAF 120/500 reads (24%) | called by mutect2, pindel, varscan2
- B4GALT5 | c.1106C>T p.A369V | Missense Mutation (SNP) | VAF 85/378 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- BARD1 | c.1655C>T p.S552F | Missense Mutation (SNP) | VAF 97/290 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- BLK | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 81/227 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- BMP5 | c.459T>G p.D153E | Missense Mutation (SNP) | VAF 86/287 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- BOD1L1 | c.2498C>T p.A833V | Missense Mutation (SNP) | VAF 102/376 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- BOD1L1 | c.292C>T p.H98Y | Missense Mutation (SNP) | VAF 93/323 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C1orf43 | c.673C>T p.P225S (on ENST00000368521 / NM_001297718.2; = p.P191S on NM_015449.4) | Missense Mutation (SNP) | VAF 97/515 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- C2orf16 | c.3351A>T p.K1117N | Missense Mutation (SNP) | VAF 112/447 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- C6 | c.1325C>T p.S442F | Missense Mutation (SNP) | VAF 73/243 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CAPN11 | c.1640G>A p.W547* | Nonsense Mutation (SNP) | VAF 62/252 reads (25%) | called by muse, mutect2, varscan2
- CCDC168 | c.11870G>A p.G3957E | Missense Mutation (SNP) | VAF 107/385 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- CDK11A | c.584_590del p.A195Gfs*10 (on ENST00000378633 / NM_001313896.2; = p.A205Gfs*10 on NM_024011.4) | Frame Shift Del (DEL) | VAF 100/537 reads (19%) | called by mutect2, varscan2
- CELF4 | c.1210C>T p.P404S | Missense Mutation (SNP) | VAF 99/426 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- CEP152 | c.275T>C p.I92T | Missense Mutation (SNP) | VAF 59/244 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CEP68 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 181/577 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- CIITA | c.1754C>T p.S585L | Missense Mutation (SNP) | VAF 125/417 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CKAP4 | c.634C>T p.L212F | Missense Mutation (SNP) | VAF 122/385 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLCN1 | c.2686A>G p.S896G | Missense Mutation (SNP) | VAF 65/566 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.024); called by muse, varscan2
- CNMD | c.530A>G p.Q177R | Missense Mutation (SNP) | VAF 105/325 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- CRTC3 | c.654A>T p.L218F | Missense Mutation (SNP) | VAF 86/308 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CRYBG2 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 126/395 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- CSRNP3 | c.209T>C p.V70A | Missense Mutation (SNP) | VAF 43/343 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CTSE | c.760C>T p.P254S (on ENST00000360218; = p.P249S on NM_001910.4) | Missense Mutation (SNP) | VAF 128/485 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DCAF8L2 | c.953G>A p.R318K | Missense Mutation (SNP) | VAF 144/511 reads (28%) | SIFT tolerated (0.78); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- DIAPH2 | c.3286G>A p.G1096R | Missense Mutation (SNP) | VAF 67/231 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- DQX1 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 116/408 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DSG1 | c.2411G>A p.G804D | Missense Mutation (SNP) | VAF 119/466 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DUOX1 | c.1042C>T p.Q348* | Nonsense Mutation (SNP) | VAF 90/334 reads (27%) | called by muse, varscan2
- DUOX1 | c.2722G>A p.G908R | Missense Mutation (SNP) | VAF 130/438 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DYNC1H1 | c.944G>A p.S315N | Missense Mutation (SNP) | VAF 53/256 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- EBF3 | c.872G>A p.G291E (on ENST00000355311 / NM_001375392.1; = p.G282E on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/348 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ELOVL3 | c.92A>G p.E31G | Missense Mutation (SNP) | VAF 103/233 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- F2RL3 | c.794G>A p.G265E | Missense Mutation (SNP) | VAF 298/553 reads (54%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- FAM13B | c.935T>G p.F312C | Missense Mutation (SNP) | VAF 45/263 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- FANCB | c.817C>T p.P273S | Missense Mutation (SNP) | VAF 148/468 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FHOD1 | c.854T>C p.L285P | Missense Mutation (SNP) | VAF 104/307 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FILIP1L | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 92/344 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- GALNT5 | c.2467A>T p.I823F | Missense Mutation (SNP) | VAF 100/334 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- GBP1 | c.1115C>T p.S372F | Missense Mutation (SNP) | VAF 116/389 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GGH | c.784C>T p.P262S | Missense Mutation (SNP) | VAF 122/383 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GGT7 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 135/470 reads (29%) | SIFT tolerated (0.74); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GKN1 | c.371A>G p.N124S | Missense Mutation (SNP) | VAF 76/362 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- GKN3P | c.34G>A p.V12I | Missense Mutation (SNP) | VAF 137/396 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GLB1 | c.431C>T p.S144F | Missense Mutation (SNP) | VAF 116/477 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- GNAS | c.1490C>T p.P497L | Missense Mutation (SNP) | VAF 162/596 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GREB1L | c.3247G>A p.E1083K | Missense Mutation (SNP) | VAF 86/575 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GRIK3 | c.206G>A p.R69K | Missense Mutation (SNP) | VAF 144/503 reads (29%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.579); called by muse, varscan2
- GRM6 | c.2348A>G p.K783R | Missense Mutation (SNP) | VAF 134/510 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- GTF2F1 | c.517C>T p.H173Y | Missense Mutation (SNP) | VAF 159/341 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- HSF2BP | c.620G>A p.S207N | Missense Mutation (SNP) | VAF 126/401 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IFT52 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 71/302 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGFBP7 | c.61C>A p.L21M | Missense Mutation (SNP) | VAF 144/464 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- IGKV1OR2-108 | c.245C>A p.S82Y | Missense Mutation (SNP) | VAF 142/473 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- IL1RAPL2 | c.563G>A p.W188* | Nonsense Mutation (SNP) | VAF 71/271 reads (26%) | called by muse, mutect2, varscan2
- IQGAP3 | c.3322C>T p.H1108Y | Missense Mutation (SNP) | VAF 266/584 reads (46%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ITPR2 | c.3772A>T p.K1258* | Nonsense Mutation (SNP) | VAF 60/232 reads (26%) | called by muse, mutect2, varscan2
- JAKMIP3 | c.1435G>A p.D479N | Missense Mutation (SNP) | VAF 109/331 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); called by muse, varscan2
- JPH3 | c.1213G>A p.A405T | Missense Mutation (SNP) | VAF 100/430 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- KCND1 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 175/643 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- KCTD15 | c.696C>T p.V232= | Splice Region (SNP) | VAF 43/403 reads (11%) | called by muse, mutect2, varscan2
- KIAA1210 | c.2662C>T p.Q888* | Nonsense Mutation (SNP) | VAF 149/520 reads (29%) | called by muse, mutect2, varscan2
- KIF27 | c.2136A>C p.L712F | Missense Mutation (SNP) | VAF 24/222 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KIR3DL1 | c.469A>G p.K157E | Missense Mutation (SNP) | VAF 109/241 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- KRTAP3-3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 42/343 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- LAMP3 | c.470G>A p.G157E | Missense Mutation (SNP) | VAF 153/514 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- LINGO4 | c.1568G>A p.G523E | Missense Mutation (SNP) | VAF 110/543 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LRRC4 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 138/607 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAN2A2 | c.1529C>T p.S510F | Missense Mutation (SNP) | VAF 111/440 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAP4K4 | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 84/319 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MCM3AP | c.2063C>T p.P688L | Missense Mutation (SNP) | VAF 137/568 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- MCM3AP | c.2062C>T p.P688S | Missense Mutation (SNP) | VAF 136/563 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- MDN1 | c.2257C>T p.Q753* | Nonsense Mutation (SNP) | VAF 109/405 reads (27%) | called by muse, mutect2, varscan2
- MED13L | c.5921G>A p.R1974Q | Missense Mutation (SNP) | VAF 115/299 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MEGF10 | c.3017C>T p.S1006F | Missense Mutation (SNP) | VAF 40/247 reads (16%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- MET | c.3383G>A p.G1128E | Missense Mutation (SNP) | VAF 95/398 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MICAL1 | c.573G>A p.G191= | Splice Region (SNP) | VAF 89/337 reads (26%) | called by muse, mutect2, varscan2
- MOGAT1 | c.127A>C p.I43L | Missense Mutation (SNP) | VAF 88/349 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MOXD1 | c.1465C>A p.Q489K | Missense Mutation (SNP) | VAF 89/308 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- MPP1 | c.248G>A p.G83E | Missense Mutation (SNP) | VAF 93/346 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MRC1 | c.2030G>A p.R677Q | Missense Mutation (SNP) | VAF 106/293 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- MTF1 | c.1666C>T p.P556S | Missense Mutation (SNP) | VAF 136/454 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MTMR1 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.242); called by muse, varscan2
- MTUS2 | c.4043C>A p.S1348Y (on ENST00000612955 / NM_001366650.1; = p.S327Y on NM_015233.6) | Missense Mutation (SNP) | VAF 163/518 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- MYO15A | c.5572A>G p.N1858D | Missense Mutation (SNP) | VAF 97/248 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NF1 | c.2384C>T p.P795L | Missense Mutation (SNP) | VAF 43/264 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- NID2 | c.1306C>T p.P436S | Missense Mutation (SNP) | VAF 118/431 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NLGN1 | c.1853A>G p.D618G | Missense Mutation (SNP) | VAF 130/500 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- NRCAM | c.1250T>C p.I417T (on ENST00000379028 / NM_001371124.1; = p.I411T on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 127/320 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NRROS | c.1304A>T p.H435L | Missense Mutation (SNP) | VAF 127/476 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- NSMF | c.815G>C p.R272P (on ENST00000371475 / NM_001130969.3; = p.R270P on NM_015537.4) | Missense Mutation (SNP) | VAF 108/435 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- NYX | c.307C>T p.P103S | Missense Mutation (SNP) | VAF 141/531 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OPRK1 | c.4G>T p.D2Y | Missense Mutation (SNP) | VAF 109/373 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- OR12D1 | c.473C>G p.S158C | Missense Mutation (SNP) | VAF 105/404 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- OR1F1 | c.785C>G p.P262R | Missense Mutation (SNP) | VAF 72/304 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- OR2G2 | c.853A>G p.T285A | Missense Mutation (SNP) | VAF 279/602 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- OR2T33 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 58/851 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.219); called by muse, mutect2
- OR2T8 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 60/663 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.139); called by muse, mutect2
- OR4F6 | c.261G>T p.R87S | Missense Mutation (SNP) | VAF 107/340 reads (31%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- PCDHA13 | c.1438C>T p.Q480* | Nonsense Mutation (SNP) | VAF 127/594 reads (21%) | called by muse, mutect2, varscan2
- PCLO | c.7450C>T p.P2484S | Missense Mutation (SNP) | VAF 222/534 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PEAR1 | c.2543A>G p.N848S | Missense Mutation (SNP) | VAF 139/761 reads (18%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- PER1 | c.2732C>T p.P911L | Missense Mutation (SNP) | VAF 50/279 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- PHF3 | c.5470C>T p.P1824S | Missense Mutation (SNP) | VAF 102/444 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- PIAS3 | c.812C>T p.S271F | Missense Mutation (SNP) | VAF 90/358 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PICALM | c.1328G>A p.S443N | Missense Mutation (SNP) | VAF 85/217 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PKHD1L1 | c.11200C>T p.P3734S | Missense Mutation (SNP) | VAF 82/294 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- POU4F2 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 128/531 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PPM1L | c.998T>G p.L333* | Nonsense Mutation (SNP) | VAF 106/417 reads (25%) | called by muse, mutect2, varscan2
- PRKAA2 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 50/417 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- PROB1 | c.3011C>T p.P1004L | Missense Mutation (SNP) | VAF 171/474 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PRORP | c.1207C>T p.P403S | Missense Mutation (SNP) | VAF 64/250 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- PSMD2 | c.1074del p.F358Lfs*13 | Frame Shift Del (DEL) | VAF 100/338 reads (30%) | called by mutect2, pindel, varscan2
- PTPRS | c.1819C>T p.P607S | Missense Mutation (SNP) | VAF 268/486 reads (55%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- PURG | c.901C>T p.L301F | Missense Mutation (SNP) | VAF 88/199 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- R3HDM2 | c.1519C>T p.Q507* | Nonsense Mutation (SNP) | VAF 90/373 reads (24%) | called by muse, mutect2, varscan2
- RBBP8NL | c.1114A>G p.S372G | Missense Mutation (SNP) | VAF 148/575 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RETREG2 | c.643T>G p.L215V | Missense Mutation (SNP) | VAF 54/215 reads (25%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- RHCE | c.455C>T p.T152I | Missense Mutation (SNP) | VAF 107/434 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RITA1 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 90/619 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RITA1 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 92/618 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ROBO2 | c.3676G>A p.E1226K | Missense Mutation (SNP) | VAF 135/485 reads (28%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- RPL7 | c.125T>C p.L42P | Missense Mutation (SNP) | VAF 75/254 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- RPP25 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 120/492 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- SEMA6C | c.985T>G p.S329A | Missense Mutation (SNP) | VAF 48/322 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SERPINB13 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 18/322 reads (6%) | SIFT tolerated (0.83); PolyPhen benign (0.007); called by muse, mutect2
- SHISA9 | c.615G>A p.M205I | Missense Mutation (SNP) | VAF 35/327 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.402); called by muse, mutect2, varscan2
- SLC16A2 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 200/736 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.307); called by muse, mutect2
- SLC16A2 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 105/380 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- SLC16A5 | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 92/484 reads (19%) | SIFT tolerated (0.55); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC16A9 | c.1238C>T p.S413F | Missense Mutation (SNP) | VAF 117/309 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC17A3 | c.403G>A p.G135R | Missense Mutation (SNP) | VAF 54/265 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC38A1 | c.307C>T p.L103F | Missense Mutation (SNP) | VAF 56/225 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- SLIT1 | c.878T>C p.V293A | Missense Mutation (SNP) | VAF 123/327 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- SMC1A | c.3507+1G>A p.X1169_splice | Splice Site (SNP) | VAF 121/396 reads (31%) | called by muse, mutect2, varscan2
- SNX29 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 109/438 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- STPG2 | c.640C>T p.P214S | Missense Mutation (SNP) | VAF 81/282 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SUN5 | c.503A>G p.K168R | Missense Mutation (SNP) | VAF 121/428 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SYNCRIP | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 71/322 reads (22%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- SYTL4 | c.245_268del p.G82_R89del | In Frame Del (DEL) | VAF 118/570 reads (21%) | called by mutect2, varscan2
- TBX22 | c.282G>A p.M94I | Missense Mutation (SNP) | VAF 130/540 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TCHHL1 | c.1370C>T p.P457L | Missense Mutation (SNP) | VAF 290/609 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TCN2 | c.65-1G>A p.X22_splice | Splice Site (SNP) | VAF 63/214 reads (29%) | called by muse, mutect2, varscan2
- TEX36 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 105/428 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TLL1 | c.470G>T p.W157L | Missense Mutation (SNP) | VAF 91/367 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TLR3 | c.2192C>T p.S731F | Missense Mutation (SNP) | VAF 127/365 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- TRAF2 | c.1451A>T p.Y484F | Missense Mutation (SNP) | VAF 132/397 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM28 | c.1637C>T p.P546L | Missense Mutation (SNP) | VAF 44/466 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2
- TRIM31 | c.701C>T p.S234F | Missense Mutation (SNP) | VAF 160/582 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.76); called by muse, mutect2
- TRIM54 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 82/275 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- TRMT1 | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 255/469 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- TSEN34 | c.577C>T p.R193* | Nonsense Mutation (SNP) | VAF 53/827 reads (6%) | called by muse, mutect2
- TTLL7 | c.1655G>A p.S552N | Missense Mutation (SNP) | VAF 131/390 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- TTN | c.5105A>T p.K1702I (on ENST00000591111; = p.K1656I on NM_003319.4) | Missense Mutation (SNP) | VAF 141/531 reads (27%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TUT7 | c.4297C>T p.L1433F | Missense Mutation (SNP) | VAF 163/490 reads (33%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- UBTD2 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 121/396 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UGT3A1 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 126/398 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- UQCRC1 | c.624C>T p.V208= | Splice Region (SNP) | VAF 84/295 reads (28%) | called by muse, mutect2, varscan2
- VPS13B | c.4675C>T p.P1559S | Missense Mutation (SNP) | VAF 86/340 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- VPS8 | c.1019C>T p.T340I (on ENST00000625842 / NM_001349294.1; = p.T338I on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 97/362 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- WDHD1 | c.2093C>T p.P698L | Missense Mutation (SNP) | VAF 71/262 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDR87 | c.7460C>T p.A2487V | Missense Mutation (SNP) | VAF 65/438 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- XKR9 | c.777G>A p.M259I | Missense Mutation (SNP) | VAF 70/260 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- YY2 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 142/504 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- ZAN | c.296G>A p.G99E | Missense Mutation (SNP) | VAF 116/518 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- ZBBX | c.659C>T p.S220F | Missense Mutation (SNP) | VAF 83/305 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ZC3HC1 | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 183/490 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFHX3 | c.3556C>A p.L1186M | Missense Mutation (SNP) | VAF 83/340 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- ZMAT5 | c.470_495del p.P157Qfs*90 | Frame Shift Del (DEL) | VAF 50/296 reads (17%) | called by pindel, varscan2
- ZNF431 | c.235T>G p.S79A | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- ZNF431 | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- ZNF683 | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 170/558 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF723 | c.1310C>T p.S437F | Missense Mutation (SNP) | VAF 150/263 reads (57%) | SIFT tolerated (0.38); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ZSCAN1 | c.752G>A p.R251K | Missense Mutation (SNP) | VAF 224/523 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZSCAN5A | c.1168G>A p.G390R | Missense Mutation (SNP) | VAF 45/381 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ABCA12 | c.6969G>A p.L2323= (on ENST00000272895 / NM_173076.3; = p.L2005= on NM_015657.3) | Silent (SNP) | VAF 87/276 reads (32%) | catalogued as rs1212656551; called by muse, mutect2, varscan2
- ABCC11 | c.1740G>A p.Q580= | Silent (SNP) | VAF 106/407 reads (26%) | called by muse, mutect2, varscan2
- AC008397.1 | c.387C>T p.S129= | Silent (SNP) | VAF 195/363 reads (54%) | called by muse, mutect2, varscan2
- AC099489.1 | c.6903C>T p.F2301= | Silent (SNP) | VAF 70/266 reads (26%) | called by muse, mutect2, varscan2
- ACD | c.150C>T p.L50= | Silent (SNP) | VAF 158/507 reads (31%) | catalogued as COSV54667962; called by muse, mutect2, varscan2
- ADAMTS6 | c.3300C>T p.F1100= | Silent (SNP) | VAF 97/346 reads (28%) | called by muse, mutect2, varscan2
- ADCY10 | c.3882C>T p.I1294= | Silent (SNP) | VAF 118/701 reads (17%) | catalogued as rs575935741, COSV63238487; called by muse, mutect2, varscan2
- ADGRD1 | c.1179G>A p.V393= | Silent (SNP) | VAF 98/360 reads (27%) | called by muse, mutect2, varscan2
- AGL | c.2349G>A p.E783= | Silent (SNP) | VAF 69/238 reads (29%) | called by muse, mutect2, varscan2
- ALMS1 | c.7332A>T p.L2444= | Silent (SNP) | VAF 129/422 reads (31%) | called by muse, mutect2, varscan2
- ALOX15B | c.1923G>A p.Q641= | Silent (SNP) | VAF 129/340 reads (38%) | called by muse, mutect2, varscan2
- AMER3 | c.2070G>A p.Q690= | Silent (SNP) | VAF 150/510 reads (29%) | catalogued as rs1188303778; called by mutect2, varscan2
- ANKRD11 | c.5364C>T p.Y1788= | Silent (SNP) | VAF 114/440 reads (26%) | catalogued as rs958706615; called by muse, mutect2, varscan2
- ARHGAP1 | c.558C>T p.I186= | Silent (SNP) | VAF 85/220 reads (39%) | called by muse, mutect2, varscan2
- ARHGAP25 | c.1338C>T p.N446= (on ENST00000409202 / NM_001007231.3; = p.N438= on NM_014882.3) | Silent (SNP) | VAF 130/490 reads (27%) | called by muse, mutect2, varscan2
- B4GALNT3 | c.2466C>T p.I822= | Silent (SNP) | VAF 92/383 reads (24%) | catalogued as rs764613664, COSV56751014; called by muse, mutect2, varscan2
- B4GALT5 | c.1107C>T p.A369= | Silent (SNP) | VAF 85/379 reads (22%) | called by muse, mutect2, varscan2
- BRPF1 | c.3345C>T p.H1115= | Silent (SNP) | VAF 87/379 reads (23%) | called by muse, mutect2, varscan2
- BRSK1 | c.1362C>T p.S454= | Silent (SNP) | VAF 129/302 reads (43%) | called by muse, mutect2, varscan2
- CAVIN4 | c.501C>T p.P167= | Silent (SNP) | VAF 103/377 reads (27%) | called by muse, mutect2, varscan2
- CC2D1B | c.1174C>T p.L392= | Silent (SNP) | VAF 106/384 reads (28%) | called by muse, mutect2, varscan2
- CCDC27 | c.1245G>A p.L415= | Silent (SNP) | VAF 96/428 reads (22%) | called by muse, mutect2, varscan2
- CCSER2 | c.2370C>T p.F790= | Silent (SNP) | VAF 117/295 reads (40%) | called by muse, mutect2, varscan2
- CD8B2 | c.240C>T p.I80= | Silent (SNP) | VAF 132/451 reads (29%) | called by muse, mutect2, varscan2
- CHIA | c.657G>A p.E219= (on ENST00000343320; = p.E111= on NM_021797.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 171/456 reads (38%) | called by muse, mutect2, varscan2
- CHRNA9 | c.1392C>T p.F464= | Silent (SNP) | VAF 102/374 reads (27%) | catalogued as COSV59575127; called by muse, mutect2, varscan2
- CHST8 | c.1107C>T p.T369= | Silent (SNP) | VAF 68/642 reads (11%) | called by muse, mutect2
- CLCN4 | c.18G>A p.A6= | Silent (SNP) | VAF 123/380 reads (32%) | catalogued as rs760994158, COSV66467662; ClinVar: likely benign; called by muse, mutect2, varscan2
- CLYBL | c.432C>T p.I144= | Silent (SNP) | VAF 54/206 reads (26%) | called by muse, mutect2, varscan2
- CNKSR2 | c.1797G>A p.K599= | Silent (SNP) | VAF 66/256 reads (26%) | called by muse, mutect2, varscan2
- CRB1 | c.1734G>A p.V578= | Silent (SNP) | VAF 258/509 reads (51%) | catalogued as COSV66330434; called by muse, mutect2, varscan2
- CTNND2 | c.2220G>A p.T740= | Silent (SNP) | VAF 93/344 reads (27%) | catalogued as rs1052851179; called by muse, mutect2, varscan2
- CTNND2 | c.363C>T p.L121= | Silent (SNP) | VAF 86/337 reads (26%) | catalogued as rs143717087, COSV58869707; called by muse, mutect2, varscan2
- CYP2A6 | c.288G>A p.E96= | Silent (SNP) | VAF 213/600 reads (36%) | catalogued as COSV56536530; called by muse, varscan2
- CYP4B1 | c.1236C>G p.L412= | Silent (SNP) | VAF 65/363 reads (18%) | called by muse, mutect2, varscan2
- DIS3L2 | c.1284C>T p.A428= | Silent (SNP) | VAF 102/366 reads (28%) | catalogued as rs1024557894, COSV56066241; called by muse, mutect2, varscan2
- DKK2 | c.747C>T p.S249= | Silent (SNP) | VAF 60/248 reads (24%) | catalogued as COSV53397726; called by muse, mutect2, varscan2
- DNAH12 | c.5598C>T p.V1866= (on ENST00000351747; = p.V1885= on NM_001366028.2) | Silent (SNP) | VAF 69/255 reads (27%) | called by muse, mutect2, varscan2
- DNAH5 | c.5565C>T p.I1855= | Silent (SNP) | VAF 114/433 reads (26%) | catalogued as rs781725837, COSV54228401, COSV54233909, COSV54237916; called by muse, mutect2, varscan2
- DSC2 | c.852C>T p.I284= | Silent (SNP) | VAF 113/463 reads (24%) | called by muse, mutect2, varscan2
- E2F1 | c.1104C>T p.P368= | Silent (SNP) | VAF 130/517 reads (25%) | catalogued as rs749886199, COSV99864994; called by muse, mutect2, varscan2
- EIF5AL1 | c.21C>T p.F7= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs1467711179, COSV101592784; called by mutect2, varscan2
- EPRS1 | c.3165C>T p.A1055= | Silent (SNP) | VAF 292/577 reads (51%) | called by muse, mutect2, varscan2
- F2RL2 | c.687C>T p.F229= | Silent (SNP) | VAF 126/426 reads (30%) | called by muse, mutect2, varscan2
- FAM222B | c.1056C>T p.V352= | Silent (SNP) | VAF 212/539 reads (39%) | catalogued as rs1382872724; called by muse, varscan2
- FGGY | c.1500C>T p.F500= | Silent (SNP) | VAF 92/324 reads (28%) | catalogued as rs115951404, COSV58031555; called by muse, mutect2, varscan2
- FREM1 | c.4578C>T p.S1526= | Silent (SNP) | VAF 161/408 reads (39%) | catalogued as rs779641943; called by muse, mutect2, varscan2
- GALNT14 | c.1599C>T p.I533= | Silent (SNP) | VAF 112/418 reads (27%) | catalogued as rs774070861, COSV61103357; called by muse, mutect2, varscan2
- GALNT17 | c.810G>A p.V270= | Silent (SNP) | VAF 102/483 reads (21%) | called by muse, mutect2, varscan2
- GC | c.643C>T p.L215= | Silent (SNP) | VAF 101/297 reads (34%) | called by muse, mutect2, varscan2
- GRIP1 | c.2328G>T p.G776= (on ENST00000359742 / NM_001379345.1; = p.G724= on NM_021150.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 108/434 reads (25%) | catalogued as COSV54017125; called by muse, mutect2, varscan2
- GRM8 | c.675G>T p.G225= | Silent (SNP) | VAF 170/517 reads (33%) | catalogued as COSV58804859; called by muse, mutect2, varscan2
- GRXCR2 | c.138G>A p.K46= | Silent (SNP) | VAF 132/369 reads (36%) | catalogued as COSV65060874; called by muse, mutect2, varscan2
- GSDMB | c.945C>T p.L315= (on ENST00000418519 / NM_001165958.1; = p.L293= on NM_018530.2) | Silent (SNP) | VAF 42/298 reads (14%) | called by mutect2, varscan2
- GYPB | c.237C>T p.L79= | Silent (SNP) | VAF 49/258 reads (19%) | catalogued as rs371821715; called by muse, mutect2, varscan2
- H2BC17 | c.285C>T p.I95= | Silent (SNP) | VAF 159/623 reads (26%) | called by muse, mutect2, varscan2
- HAO1 | c.735G>A p.R245= | Silent (SNP) | VAF 99/302 reads (33%) | called by muse, mutect2, varscan2
- HECTD4 | c.1137C>T p.F379= | Silent (SNP) | VAF 62/245 reads (25%) | called by muse, mutect2, varscan2
- HERC2 | c.2703G>A p.A901= | Silent (SNP) | VAF 171/536 reads (32%) | catalogued as rs745376326; called by muse, mutect2, varscan2
- HMGB4 | c.300C>T p.F100= | Silent (SNP) | VAF 147/560 reads (26%) | catalogued as COSV53932002; called by muse, mutect2, varscan2
- HYDIN | c.2940G>A p.R980= | Silent (SNP) | VAF 61/345 reads (18%) | called by muse, mutect2, varscan2
- IL21R | c.1560C>T p.L520= | Silent (SNP) | VAF 134/460 reads (29%) | called by muse, mutect2, varscan2
- ILF2 | c.903C>T p.V301= | Silent (SNP) | VAF 69/291 reads (24%) | catalogued as rs1260260737, COSV62627900; called by muse, mutect2, varscan2
- INPP5E | c.1173C>T p.S391= | Silent (SNP) | VAF 93/302 reads (31%) | called by muse, mutect2, varscan2
- IP6K2 | c.63C>T p.P21= | Silent (SNP) | VAF 181/625 reads (29%) | called by muse, mutect2, varscan2
- ITGAD | c.942G>A p.K314= | Silent (SNP) | VAF 90/376 reads (24%) | called by muse, varscan2
- ITGB4 | c.3210C>T p.L1070= | Silent (SNP) | VAF 117/579 reads (20%) | called by muse, mutect2, varscan2
- ITIH5 | c.1146G>A p.R382= | Silent (SNP) | VAF 37/271 reads (14%) | catalogued as COSV53669864; called by muse, mutect2, varscan2
- ITPKB | c.924G>A p.A308= | Silent (SNP) | VAF 74/882 reads (8%) | called by muse, mutect2
- JAKMIP2 | c.483G>A p.T161= | Silent (SNP) | VAF 140/370 reads (38%) | called by muse, mutect2, varscan2
- JCAD | c.1683C>T p.F561= | Silent (SNP) | VAF 107/296 reads (36%) | called by muse, mutect2, varscan2
- KIF2B | c.1569G>A p.G523= | Silent (SNP) | VAF 237/558 reads (42%) | called by muse, mutect2, varscan2
- KRT16 | c.633C>T p.A211= | Silent (SNP) | VAF 91/264 reads (34%) | catalogued as rs765449152; called by muse, mutect2, varscan2
- LAMB3 | c.3174C>T p.V1058= | Silent (SNP) | VAF 140/732 reads (19%) | called by muse, mutect2, varscan2
- LDHA | c.172T>C p.L58= | Silent (SNP) | VAF 91/222 reads (41%) | catalogued as rs749220974; called by muse, mutect2, varscan2
- LDLRAD4 | c.612C>T p.S204= | Silent (SNP) | VAF 132/472 reads (28%) | catalogued as rs534294494; called by muse, mutect2, varscan2
- LMOD3 | c.507G>A p.T169= | Silent (SNP) | VAF 132/477 reads (28%) | catalogued as rs1345777816; called by muse, mutect2, varscan2
- LPAR3 | c.255C>T p.F85= | Silent (SNP) | VAF 121/348 reads (35%) | catalogued as COSV65453004; called by muse, mutect2, varscan2
- LRRC18 | c.564C>T p.F188= | Silent (SNP) | VAF 108/319 reads (34%) | called by muse, mutect2, varscan2
- MAGEB17 | c.333G>A p.T111= | Silent (SNP) | VAF 160/600 reads (27%) | catalogued as rs949113851; called by muse, mutect2, varscan2
- MAGEB4 | c.306G>A p.E102= | Silent (SNP) | VAF 147/528 reads (28%) | called by muse, mutect2, varscan2
- MAGI1 | c.969G>A p.T323= | Silent (SNP) | VAF 58/234 reads (25%) | catalogued as rs267599924, COSV58333620; called by muse, mutect2, varscan2
- MALRD1 | c.2955G>A p.R985= | Silent (SNP) | VAF 92/229 reads (40%) | called by muse, mutect2, varscan2
- MALRD1 | c.5373C>T p.S1791= | Silent (SNP) | VAF 104/264 reads (39%) | catalogued as rs769427279; called by muse, mutect2, varscan2
- MAN1C1 | c.1326G>A p.G442= | Silent (SNP) | VAF 155/582 reads (27%) | catalogued as COSV56041350; called by muse, mutect2, varscan2
- MAOA | c.57C>T p.I19= | Silent (SNP) | VAF 125/466 reads (27%) | called by muse, mutect2, varscan2
- MAPK4 | c.144G>A p.V48= | Silent (SNP) | VAF 148/568 reads (26%) | called by muse, mutect2
- MAST3 | c.1920C>T p.F640= | Silent (SNP) | VAF 209/393 reads (53%) | called by muse, mutect2, varscan2
- MGAM | c.2802G>A p.L934= | Silent (SNP) | VAF 115/275 reads (42%) | catalogued as COSV72075010; called by muse, mutect2, varscan2
- MYO18B | c.7059C>T p.S2353= | Silent (SNP) | VAF 119/464 reads (26%) | called by muse, mutect2, varscan2
- MYO7B | c.267C>T p.Y89= | Silent (SNP) | VAF 88/315 reads (28%) | called by muse, mutect2, varscan2
- MYT1L | c.1602C>T p.V534= | Silent (SNP) | VAF 76/315 reads (24%) | called by muse, mutect2, varscan2
- NADSYN1 | c.1752C>T p.S584= | Silent (SNP) | VAF 78/232 reads (34%) | called by muse, mutect2, varscan2
- NBEAL2 | c.6675C>T p.F2225= | Silent (SNP) | VAF 87/321 reads (27%) | called by muse, mutect2, varscan2
- NEK1 | c.3606C>T p.F1202= | Silent (SNP) | VAF 64/246 reads (26%) | catalogued as COSV71454497; called by muse, mutect2, varscan2
- NLRP4 | c.963C>T p.A321= | Silent (SNP) | VAF 140/348 reads (40%) | catalogued as rs267605698; called by muse, mutect2, varscan2
- NME8 | c.156G>A p.L52= | Silent (SNP) | VAF 73/349 reads (21%) | called by muse, mutect2, varscan2
- NOS3 | c.909C>T p.F303= | Silent (SNP) | VAF 36/584 reads (6%) | called by muse, mutect2
- NPSR1 | c.30C>T p.F10= | Silent (SNP) | VAF 121/390 reads (31%) | catalogued as rs267601494, COSV62197912, COSV62198954; called by muse, mutect2, varscan2
- NRXN3 | c.1596C>T p.F532= | Silent (SNP) | VAF 126/514 reads (25%) | catalogued as COSV99819507; called by muse, mutect2, varscan2
- NUTM1 | c.1083G>A p.K361= | Silent (SNP) | VAF 144/487 reads (30%) | catalogued as rs267604159, COSV59219013; called by muse, mutect2, varscan2
- NUTM2A | c.2607G>A p.R869= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as rs1353991444; called by mutect2, varscan2
- OR10K1 | c.642C>T p.I214= | Silent (SNP) | VAF 288/559 reads (52%) | called by muse, mutect2, varscan2
- OR12D1 | c.474C>T p.S158= | Silent (SNP) | VAF 96/376 reads (26%) | called by muse, varscan2
- OR14A2 | c.180C>T p.F60= | Silent (SNP) | VAF 281/531 reads (53%) | called by muse, mutect2, varscan2
- OR1J2 | c.699G>A p.G233= | Silent (SNP) | VAF 102/402 reads (25%) | called by muse, mutect2, varscan2
- OR2A25 | c.78C>T p.L26= | Silent (SNP) | VAF 145/464 reads (31%) | catalogued as COSV101376330, COSV101376373; called by muse, mutect2, varscan2
- OR2T8 | c.45C>T p.L15= | Silent (SNP) | VAF 270/541 reads (50%) | called by muse, mutect2, varscan2
- OR4C5 | c.780C>T p.V260= | Silent (SNP) | VAF 68/207 reads (33%) | catalogued as rs200811929; called by muse, mutect2, varscan2
- OR4M1 | c.183C>T p.F61= | Silent (SNP) | VAF 113/764 reads (15%) | catalogued as COSV60060150; called by muse, mutect2, varscan2
- OR6C65 | c.891G>A p.Q297= | Silent (SNP) | VAF 88/299 reads (29%) | catalogued as rs1565680844; called by muse, mutect2, varscan2
- OR6Y1 | c.660G>T p.V220= | Silent (SNP) | VAF 40/726 reads (6%) | called by muse, mutect2
- OR7G2 | c.294G>A p.T98= | Silent (SNP) | VAF 223/379 reads (59%) | catalogued as rs377637744; called by muse, mutect2, varscan2
- PABPN1 | c.549A>G p.A183= | Silent (SNP) | VAF 52/247 reads (21%) | called by muse, mutect2, varscan2
- PADI1 | c.45C>T p.T15= | Silent (SNP) | VAF 91/374 reads (24%) | called by muse, mutect2, varscan2
- PATJ | c.1702C>T p.L568= | Silent (SNP) | VAF 117/329 reads (36%) | called by muse, mutect2, varscan2
- PCDHA7 | c.144C>T p.I48= | Silent (SNP) | VAF 84/495 reads (17%) | catalogued as COSV65342235, COSV65347101; called by muse, mutect2, varscan2
- PCDHB1 | c.1197G>A p.G399= | Silent (SNP) | VAF 99/250 reads (40%) | catalogued as COSV60629509; called by muse, mutect2, varscan2
- PCDHGA9 | c.633C>T p.V211= | Silent (SNP) | VAF 63/434 reads (15%) | called by muse, mutect2, varscan2
- PEX14 | c.249C>T p.A83= | Silent (SNP) | VAF 90/325 reads (28%) | called by muse, mutect2, varscan2
- PEX5 | c.1882C>T p.L628= (on ENST00000420616; = p.L620= on NM_000319.5) | Silent (SNP) | VAF 126/400 reads (32%) | called by muse, mutect2, varscan2
- PICK1 | c.27C>T p.I9= | Silent (SNP) | VAF 41/318 reads (13%) | catalogued as COSV100811115; called by muse, mutect2, varscan2
- PIK3IP1 | c.420G>A p.R140= | Silent (SNP) | VAF 127/484 reads (26%) | called by muse, mutect2, varscan2
- PKD2L1 | c.702A>G p.Q234= | Silent (SNP) | VAF 96/205 reads (47%) | catalogued as rs757396282; called by muse, mutect2, varscan2
- PLA2G4E | c.1812G>A p.R604= | Silent (SNP) | VAF 91/359 reads (25%) | catalogued as COSV68149863; called by muse, mutect2, varscan2
- PLCB4 | c.2400C>T p.S800= | Silent (SNP) | VAF 112/381 reads (29%) | catalogued as COSV53807406; called by muse, mutect2, varscan2
- PLOD3 | c.984C>T p.V328= | Silent (SNP) | VAF 118/412 reads (29%) | called by muse, mutect2, varscan2
- PNPLA3 | c.252C>T p.F84= | Silent (SNP) | VAF 118/406 reads (29%) | called by muse, mutect2
- PODN | c.828C>T p.F276= (on ENST00000395871; = p.F228= on NM_153703.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 167/538 reads (31%) | called by muse, mutect2, varscan2
- POM121L2 | c.2715C>T p.I905= | Silent (SNP) | VAF 113/390 reads (29%) | called by muse, mutect2, varscan2
- POTEJ | c.2091C>T p.I697= | Silent (SNP) | VAF 172/704 reads (24%) | catalogued as rs776332310; called by mutect2, varscan2
- PPIAL4G | c.33C>T p.T11= | Silent (SNP) | VAF 40/624 reads (6%) | catalogued as rs1465142768, COSV101344014; called by muse, mutect2
- PPP2R2C | c.630C>T p.I210= | Silent (SNP) | VAF 71/278 reads (26%) | catalogued as rs756692262, COSV58673716; called by muse, mutect2, varscan2
- PRAMEF11 | c.1116C>T p.I372= | Silent (SNP) | VAF 107/500 reads (21%) | catalogued as rs1159279863; called by muse, mutect2, varscan2
- PSG9 | c.1137C>T p.L379= | Silent (SNP) | VAF 237/501 reads (47%) | catalogued as COSV99392427; called by muse, mutect2, varscan2
- PTK7 | c.1386G>A p.K462= | Silent (SNP) | VAF 89/338 reads (26%) | called by muse, mutect2, varscan2
- PTPRT | c.2002T>C p.L668= | Silent (SNP) | VAF 118/388 reads (30%) | catalogued as COSV61957384, COSV61969153; called by muse, mutect2, varscan2
- RAB25 | c.351G>A p.T117= | Silent (SNP) | VAF 284/568 reads (50%) | catalogued as rs1438147085, COSV63108486; called by muse, mutect2, varscan2
- RADIL | c.3138C>T p.I1046= | Silent (SNP) | VAF 108/337 reads (32%) | called by muse, mutect2, varscan2
- RAPGEFL1 | c.702T>C p.L234= | Silent (SNP) | VAF 119/363 reads (33%) | called by muse, mutect2, varscan2
- RHBDD1 | c.210C>T p.L70= | Silent (SNP) | VAF 147/576 reads (26%) | called by muse, mutect2, varscan2
- RSPH10B2 | c.1896C>T p.L632= | Silent (SNP) | VAF 8/36 reads (22%) | called by mutect2, varscan2
- RTL1 | c.3006G>A p.R1002= | Silent (SNP) | VAF 135/484 reads (28%) | catalogued as COSV66017397; called by muse, mutect2, varscan2
- RTL3 | c.924C>T p.F308= | Silent (SNP) | VAF 140/524 reads (27%) | catalogued as COSV58183099; called by muse, mutect2, varscan2
- RTL3 | c.96T>A p.A32= | Silent (SNP) | VAF 142/478 reads (30%) | called by muse, mutect2, varscan2
- SARS1 | c.597C>T p.V199= | Silent (SNP) | VAF 76/236 reads (32%) | called by muse, mutect2, varscan2
- SCN5A | c.5268C>T p.I1756= (on ENST00000333535 / NM_198056.3; = p.I1755= on NM_000335.5) | Silent (SNP) | VAF 122/504 reads (24%) | called by muse, mutect2, varscan2
- SDK1 | c.3288G>A p.G1096= | Silent (SNP) | VAF 142/409 reads (35%) | catalogued as COSV67357891; called by muse, mutect2, varscan2
- SELENOP | c.1053C>T p.A351= | Silent (SNP) | VAF 50/349 reads (14%) | catalogued as rs754855834; called by muse, mutect2, varscan2
- SERPINB4 | c.39C>T p.F13= | Silent (SNP) | VAF 36/289 reads (12%) | catalogued as rs201764023, COSV61984146, COSV61984596; called by muse, mutect2, varscan2
- SH3BP5L | c.345C>T p.P115= | Silent (SNP) | VAF 58/397 reads (15%) | called by muse, mutect2, varscan2
- SH3PXD2B | c.1647C>T p.L549= | Silent (SNP) | VAF 156/577 reads (27%) | called by muse, mutect2, varscan2
- SLC13A5 | c.939C>T p.S313= | Silent (SNP) | VAF 116/322 reads (36%) | called by muse, mutect2, varscan2
- SLC16A2 | c.1041G>A p.E347= | Silent (SNP) | VAF 103/375 reads (27%) | called by muse, mutect2, varscan2
- SLC22A3 | c.420C>T p.I140= | Silent (SNP) | VAF 47/350 reads (13%) | catalogued as rs753633030; called by muse, mutect2, varscan2
- SLC7A3 | c.609C>T p.F203= | Silent (SNP) | VAF 173/586 reads (30%) | catalogued as rs1282780743, COSV53226730; called by muse, mutect2, varscan2
- SLCO1B1 | c.1224C>T p.A408= | Silent (SNP) | VAF 88/307 reads (29%) | called by muse, mutect2, varscan2
- SLCO5A1 | c.1083G>A p.V361= | Silent (SNP) | VAF 85/305 reads (28%) | called by muse, mutect2, varscan2
- SLCO6A1 | c.183C>T p.F61= | Silent (SNP) | VAF 104/406 reads (26%) | catalogued as rs1408549820, COSV101135161, COSV65811595; called by muse, mutect2, varscan2
- SORCS1 | c.3354C>T p.V1118= | Silent (SNP) | VAF 104/235 reads (44%) | catalogued as rs896136945; called by muse, mutect2, varscan2
- SPO11 | c.39C>T p.F13= | Silent (SNP) | VAF 102/390 reads (26%) | called by muse, mutect2, varscan2
- SPTY2D1 | c.357C>T p.T119= | Silent (SNP) | VAF 111/328 reads (34%) | catalogued as rs976264170, COSV100311866; called by muse, mutect2, varscan2
- STK36 | c.939C>T p.A313= | Silent (SNP) | VAF 49/321 reads (15%) | catalogued as COSV55326272; called by muse, mutect2, varscan2
- SURF6 | c.846C>T p.I282= | Silent (SNP) | VAF 150/575 reads (26%) | catalogued as COSV64395881; called by muse, mutect2, varscan2
- TEC | c.549C>T p.I183= | Silent (SNP) | VAF 104/364 reads (29%) | catalogued as rs574810323, COSV101202650; called by muse, mutect2, varscan2
- TECPR2 | c.2457C>G p.S819= | Silent (SNP) | VAF 38/329 reads (12%) | catalogued as rs765475573; called by muse, mutect2, varscan2
- TENM2 | c.2514C>T p.P838= (on ENST00000518659 / NM_001122679.2; = p.P606= on NM_001080428.3) | Silent (SNP) | VAF 97/356 reads (27%) | catalogued as rs764275120, COSV69122459; called by muse, mutect2, varscan2
- TLR4 | c.1659C>A p.L553= (on ENST00000355622 / NM_138554.5; = p.L513= on NM_003266.4) | Silent (SNP) | VAF 114/391 reads (29%) | catalogued as COSV62923152; called by muse, mutect2, varscan2
- TLR5 | c.1173C>T p.L391= | Silent (SNP) | VAF 293/538 reads (54%) | catalogued as COSV60559009; called by muse, mutect2, varscan2
- TMEM211 | c.372C>T p.F124= (on ENST00000423535; = p.F53= on NM_001001663.3) | Silent (SNP) | VAF 95/362 reads (26%) | catalogued as COSV66954140; called by muse, mutect2, varscan2
- TP53BP2 | c.273C>T p.P91= | Silent (SNP) | VAF 85/505 reads (17%) | catalogued as rs772539539; called by muse, mutect2, varscan2
- TRDN | c.1395G>A p.K465= | Silent (SNP) | VAF 6/95 reads (6%) | called by muse, mutect2
- TRIM28 | c.1638C>T p.P546= | Silent (SNP) | VAF 44/463 reads (10%) | catalogued as COSV99449414; called by muse, mutect2
- TRIOBP | c.6879C>T p.L2293= (on ENST00000644935 / NM_001039141.3; = p.L580= on NM_007032.5) | Silent (SNP) | VAF 75/329 reads (23%) | called by muse, mutect2, varscan2
- TSNAX | c.306C>T p.F102= | Silent (SNP) | VAF 247/497 reads (50%) | called by muse, mutect2, varscan2
- TTN | c.62994G>A p.K20998= (on ENST00000591111; = p.K13574= on NM_003319.4) | Silent (SNP) | VAF 156/506 reads (31%) | catalogued as rs772213947; called by muse, mutect2, varscan2
- UGT2B15 | c.1158C>T p.Y386= | Silent (SNP) | VAF 130/604 reads (22%) | called by muse, varscan2
- UGT2B17 | c.1329C>T p.I443= | Silent (SNP) | VAF 80/296 reads (27%) | called by muse, mutect2, varscan2
- USP21 | c.744G>A p.E248= | Silent (SNP) | VAF 69/470 reads (15%) | called by muse, mutect2, varscan2
- VN1R4 | c.336G>A p.R112= | Silent (SNP) | VAF 54/356 reads (15%) | catalogued as COSV60804690; called by muse, mutect2, varscan2
- WDR44 | c.1692C>T p.P564= | Silent (SNP) | VAF 118/333 reads (35%) | called by muse, mutect2, varscan2
- WFDC1 | c.51G>A p.R17= | Silent (SNP) | VAF 135/491 reads (27%) | catalogued as rs762841944; called by muse, mutect2, varscan2
- WNT2 | c.759C>T p.F253= | Silent (SNP) | VAF 130/534 reads (24%) | called by muse, mutect2, varscan2
- XIRP2 | c.9450C>T p.F3150= (on ENST00000628543; = p.F3325= on NM_152381.6) | Silent (SNP) | VAF 110/385 reads (29%) | catalogued as rs1553505593, COSV54686043, COSV54714181; called by muse, mutect2, varscan2
- XK | c.870C>A p.I290= | Silent (SNP) | VAF 54/498 reads (11%) | catalogued as COSV66119832; called by muse, mutect2, varscan2
- YEATS2 | c.1608C>T p.S536= | Silent (SNP) | VAF 91/356 reads (26%) | called by muse, mutect2, varscan2
- ZAN | c.297G>A p.G99= | Silent (SNP) | VAF 115/519 reads (22%) | catalogued as rs1488188998; called by muse, mutect2, varscan2
- ZBTB9 | c.156C>T p.L52= | Silent (SNP) | VAF 162/672 reads (24%) | called by muse, mutect2, varscan2
- ZBTB9 | c.157C>T p.L53= | Silent (SNP) | VAF 162/672 reads (24%) | called by muse, mutect2, varscan2
- ZCCHC14 | c.1161C>T p.P387= (on ENST00000268616; = p.P524= on NM_015144.3) | Silent (SNP) | VAF 136/526 reads (26%) | catalogued as rs770768449; called by muse, mutect2, varscan2
- ZNF280A | c.1572G>A p.K524= | Silent (SNP) | VAF 94/397 reads (24%) | catalogued as COSV57480896; called by muse, mutect2, varscan2
- ZNF613 | c.30G>A p.L10= | Silent (SNP) | VAF 22/198 reads (11%) | called by muse, mutect2, varscan2
- ZNF835 | c.1572G>A p.Q524= | Silent (SNP) | VAF 48/382 reads (13%) | catalogued as rs778095708, COSV73379755; called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130914863 C>T | 5'Flank (SNP) | VAF 79/281 reads (28%) | called by muse, mutect2, varscan2
- ARMCX4 | c.1039-3263G>A | Intron (SNP) | VAF 114/461 reads (25%) | called by muse, mutect2, varscan2
- AZIN1 | c.-148C>T | 5'UTR (SNP) | VAF 116/401 reads (29%) | called by muse, mutect2, varscan2
- BCL11A | c.386-6322C>T | Intron (SNP) | VAF 65/241 reads (27%) | catalogued as rs768003232, COSV59629381; called by muse, mutect2, varscan2
- C4orf50 | chr4:5990164 G>A | 5'Flank (SNP) | VAF 74/277 reads (27%) | called by muse, mutect2, varscan2
- CARNS1 | c.-50G>A | 5'UTR (SNP) | VAF 142/346 reads (41%) | catalogued as COSV57131951; called by muse, mutect2
- CUTA | chr6:33418154 C>T | 5'Flank (SNP) | VAF 127/504 reads (25%) | catalogued as rs746349836; called by muse, mutect2, varscan2
- CUTA | chr6:33418155 C>T | 5'Flank (SNP) | VAF 126/496 reads (25%) | catalogued as rs180788417; called by muse, mutect2, varscan2
- ERGIC1 | c.375+39C>T | Intron (SNP) | VAF 121/384 reads (32%) | catalogued as rs1356706870, COSV100442680; called by muse, mutect2, varscan2
- FUT9 | c.*8038G>A | 3'UTR (SNP) | VAF 86/360 reads (24%) | called by muse, mutect2, varscan2
- IKZF1 | c.161-8421C>T | Intron (SNP) | VAF 146/422 reads (35%) | called by muse, mutect2
- ITGAD | c.-1G>A | 5'UTR (SNP) | VAF 71/346 reads (21%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-18993G>A | Intron (SNP) | VAF 51/125 reads (41%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+10866G>A | Intron (SNP) | VAF 89/225 reads (40%) | called by muse, mutect2, varscan2
- LCK | c.965-64G>A | Intron (SNP) | VAF 108/359 reads (30%) | catalogued as rs984710906, COSV60741641; called by muse, mutect2, varscan2
- MCF2 | chrX:139645629 A>T | 5'Flank (SNP) | VAF 108/345 reads (31%) | called by muse, mutect2, varscan2
- MEX3B | c.256+40T>C | Intron (SNP) | VAF 96/397 reads (24%) | catalogued as rs375213012; called by muse, mutect2, varscan2
- OGG1 | c.*114C>A | 3'UTR (SNP) | VAF 82/559 reads (15%) | called by muse, mutect2, varscan2
- PHLDB2 | c.1335+98G>A | Intron (SNP) | VAF 120/419 reads (29%) | catalogued as rs267599544; called by muse, mutect2, varscan2
- PSKH1 | c.957+60C>T | Intron (SNP) | VAF 158/508 reads (31%) | catalogued as rs1273659300; called by muse, mutect2, varscan2
- RAC2 | c.107+449G>A | Intron (SNP) | VAF 83/294 reads (28%) | called by muse, mutect2, varscan2
- SLC22A17 | n.971G>A | RNA (SNP) | VAF 122/517 reads (24%) | catalogued as COSV52835672; called by muse, mutect2, varscan2
- TTN | c.10361-4188G>A | Intron (SNP) | VAF 91/346 reads (26%) | catalogued as rs141483365; called by muse, mutect2, varscan2
- TTN | c.10360+1614G>A | Intron (SNP) | VAF 98/352 reads (28%) | catalogued as rs749558211, COSV100594766; called by muse, mutect2, varscan2
- XIST | n.10624C>T | RNA (SNP) | VAF 71/245 reads (29%) | called by muse, mutect2, varscan2
- ZNF812P | n.644G>A | RNA (SNP) | VAF 213/385 reads (55%) | called by muse, mutect2, varscan2
